Somatic mutation profile of tumor specimen TARGET-20-PARUCB-04A (aliquot TARGET-20-PARUCB-04A-01D) from TARGET case TARGET-20-PARUCB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.3 years (4,121 days).
Specimen TARGET-20-PARUCB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91b37a81-283f-40c8-8c58-387f8eb1192d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUCB-14A (Bone Marrow Normal), aliquot TARGET-20-PARUCB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d64e50a4-08f0-4b41-8a4f-2f334554761b

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.934_936dup p.Q312dup | In Frame Ins (INS) | VAF 11/44 reads (25%) | catalogued as COSV57198430; called by mutect2, varscan2
- SYCE1 | c.694C>G p.R232G (on ENST00000343131 / NM_001143764.3; = p.R196G on NM_130784.3) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58218434; called by muse, mutect2, varscan2
- MAP4K2 | c.1358_1365+17del p.X453_splice | Splice Site (DEL) | VAF 23/127 reads (18%) | called by mutect2, pindel, varscan2
- PRKAG3 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- FCER2 | c.168G>T p.L56= | Silent (SNP) | VAF 72/202 reads (36%) | called by muse, mutect2
- HNRNPA1 | c.39G>T p.L13= | Silent (SNP) | VAF 75/165 reads (45%) | called by muse, mutect2, varscan2
